Gene-level copy-number profile of tumor specimen TCGA-92-7340-01A from TCGA case TCGA-92-7340, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.0 years (16,447 days).
Specimen TCGA-92-7340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.60b5737b-75ef-475a-b7de-f6ceda4344d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-92-7340-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b44852b-e58d-465e-b4ef-1e6080c1dbb9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 151; copy number 2: 17,659; copy number 3: 14,214; copy number 4: 19,571; copy number 5: 4,168; copy number 6: 3,406; copy number 8: 121; copy number 9: 84; copy number 10: 230; copy number 12: 128; copy number 19: 30; copy number 24: 4; copy number 27: 39; copy number 42: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-92-7340-01A-21D-2041-01): tumor purity 0.39, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 400 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:199,608,068–203,226,378, 123 genes, copy number 9–27 (within-gene range 2–27) (broad region; genes not listed).
- chr4:56,760,919–60,038,586, 40 genes, copy number 19–42: AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:72,807,267–78,544,269, 119 genes, copy number 10 (broad region; genes not listed).
- chr4:159,375,099–159,777,828, 3 genes, copy number 12: AC074344.1, AC074344.2, LINC02233.
- chr4:181,064,089–186,289,681, 109 genes, copy number 10 (broad region; genes not listed).
- chr4:186,326,302–186,336,662, 2 genes, copy number 10: AC109517.1, SLC25A5P6.
- chr10:8,897,989–9,309,772, 4 genes, copy number 24: LINC02676, AC044784.1, LINC00709, AL138773.1.

Autosomal genes at a single copy (total copy number 1): 151. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
